Somatic mutation profile of tumor specimen MMRF_1682_1_BM_CD138pos (aliquot MMRF_1682_1_BM_CD138pos_T1_KBS5U_L05782) from MMRF case MMRF_1682, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.2 years (26,379 days).
Specimen MMRF_1682_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aadda056-2f90-4e01-ad42-9ac85f8ffd07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1682_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1682_1_PB_WBC_C3_KBS5U_L05796; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fefb9b6-1d2d-4358-9ed9-d59bb45dc3ba

The open-access MAF lists 210 somatic variants for this specimen: 79 protein-altering or splice-affecting, 23 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 64, Intron 24, Silent 23, 5'UTR 12, Frame Shift Del 4, 5'Flank 4, Nonsense Mutation 3, 3'Flank 3, Splice Site 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP295NL | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs978770019; called by muse, mutect2, varscan2
- CFAP251 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV56612330; called by muse, mutect2, varscan2
- CFAP43 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs145913363, COSV53376560; called by muse, mutect2, varscan2
- CHST7 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52100298; called by muse, mutect2, varscan2
- COL24A1 | c.3807del p.G1270Efs*68 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | catalogued as rs751232308; called by mutect2, pindel, varscan2
- CSMD3 | c.10660T>G p.L3554V (on ENST00000297405 / NM_001363185.1; = p.L3385V on NM_052900.3) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52339817; called by muse, mutect2, varscan2
- DNAH10 | c.6385G>A p.V2129I (on ENST00000409039; = p.V2068I on NM_207437.3) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs557513283, COSV68992263; called by muse, mutect2, varscan2
- ERCC6L2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.093); catalogued as rs769611647; called by muse, mutect2, varscan2
- GABRG2 | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62717806; called by muse, mutect2, varscan2
- GHRHR | c.844T>A p.W282R | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58196263; called by muse, mutect2, varscan2
- GOLGA6L2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs762579164, COSV61479887; called by muse, mutect2, varscan2
- GRIN2B | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs201335987, COSV101663174, COSV74205415, COSV74206068; called by muse, mutect2, varscan2
- GUCY2D | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1322820848; called by muse, mutect2
- H1-2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs553002000, COSV59191114; called by muse, mutect2, varscan2
- IGHV2-70 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs188243654; called by muse, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, varscan2
- IGLV3-1 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs369317662; called by muse, varscan2
- IGLV3-1 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs367981147; called by muse, varscan2
- IGLV3-1 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs568311535; called by muse, varscan2
- INSYN2A | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54738736; called by muse, mutect2, varscan2
- JUP | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as rs781982717, CM107150; ClinVar: uncertain significance; called by muse, mutect2
- POU5F2 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs768126763; called by muse, mutect2, varscan2
- PTPRK | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374539512; called by muse, mutect2, varscan2
- RNF183 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs373858981; called by muse, mutect2, varscan2
- SLC9A2 | c.1672A>T p.K558* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV52134300; called by muse, mutect2
- TAF4B | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99300242; called by muse, mutect2, varscan2
- TTYH2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773763545, COSV53909676; called by muse, mutect2, varscan2
- ZFP42 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 97/164 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750318279, COSV58817208, COSV58818962; called by muse, mutect2, varscan2
- ZNF804A | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56459317; called by muse, mutect2, varscan2
- ADAM28 | c.1433G>T p.C478F | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADH6 | c.1093A>C p.T365P | Missense Mutation (SNP) | VAF 172/292 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- BDP1 | c.1985C>G p.T662R | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2
- BHLHE41 | c.798_807del p.K266Nfs*12 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- CDC20 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CDC42BPB | c.2414C>A p.A805E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CDH19 | c.1959del p.F654Lfs*3 | Frame Shift Del (DEL) | VAF 60/314 reads (19%) | called by mutect2, pindel, varscan2
- CEP295NL | c.198C>G p.S66R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CFAP47 | c.4414A>C p.T1472P | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CLHC1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL2A1 | c.4343_4344del p.T1448Sfs*16 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | called by mutect2, varscan2
- EPS8L3 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FILIP1 | c.1317A>C p.E439D | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.1186A>C p.N396H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FYB2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GNPDA1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA12A | c.733T>A p.Y245N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- HSPB11 | c.205+2T>C p.X69_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- HTR3A | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHA1 | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- IGHV2-70D | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, varscan2
- IGLV4-3 | c.180dup p.R61Efs*10 | Frame Shift Ins (INS) | VAF 44/147 reads (30%) | called by pindel, varscan2*
- ITGA1 | c.1984T>G p.F662V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ITGA2 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KDM2A | c.1086T>A p.D362E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KLK2 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KNDC1 | c.2144T>G p.L715R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KRT34 | c.171C>G p.S57R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MARF1 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MUC16 | c.14053T>G p.S4685A | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OLR1 | c.218A>C p.N73T | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OR8K5 | c.920A>T p.N307I | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PCDH10 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLSCR2 | c.595C>T p.H199Y (on ENST00000497985 / NM_001199978.1; = p.H126Y on NM_020359.2) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PSEN1 | c.405T>G p.N135K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMB3 | c.595A>C p.T199P | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- R3HCC1L | c.903T>G p.D301E | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2
- RIMS1 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2
- SEL1L2 | c.1254C>A p.Y418* | Nonsense Mutation (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- SLCO5A1 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRPX | c.350-2A>C p.X117_splice | Splice Site (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- TAP2 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TBX5 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIMELESS | c.3472A>T p.K1158* | Nonsense Mutation (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- TOR4A | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TPM2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- TPM2 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ZDBF2 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF26 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ADRB1 | c.555C>T p.I185= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV65168366; called by muse, mutect2
- BHLHE41 | c.1045C>T p.L349= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1345902255; called by muse, mutect2, varscan2
- BHLHE41 | c.1044C>T p.C348= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1176479634; called by muse, mutect2, varscan2
- CALD1 | c.1644C>T p.S548= (on ENST00000361675 / NM_033138.4; = p.S293= on NM_004342.7) | Silent (SNP) | VAF 13/89 reads (15%) | called by mutect2, varscan2
- CAMSAP3 | c.1926G>A p.P642= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs1295505392; called by muse, mutect2, varscan2
- CD36 | c.1323T>A p.L441= | Silent (SNP) | VAF 38/227 reads (17%) | called by muse, mutect2, varscan2
- FAM102A | c.136T>C p.L46= | Silent (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- IL4R | c.858G>A p.Q286= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- KALRN | c.2436G>A p.Q812= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as COSV53774257; called by muse, mutect2, varscan2
- NANOS1 | c.483G>A p.V161= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- NFE2L1 | c.201C>T p.I67= | Silent (SNP) | VAF 11/288 reads (4%) | catalogued as rs1383638813; called by muse, mutect2
- NKAIN3 | c.279C>T p.T93= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs148093471; called by muse, mutect2, varscan2
- NSUN7 | c.759T>C p.F253= | Silent (SNP) | VAF 47/72 reads (65%) | called by muse, mutect2, varscan2
- NTNG2 | c.630C>T p.H210= | Silent (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- ONECUT2 | c.1071G>A p.A357= | Silent (SNP) | VAF 37/199 reads (19%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1827C>T p.Y609= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- PLXNA3 | c.855C>T p.R285= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as rs192841912, COSV63754258; called by muse, mutect2, varscan2
- RBM20 | c.2241C>T p.H747= | Silent (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- RGS3 | c.2583G>A p.L861= (on ENST00000350696 / NM_001282923.2; = p.L580= on NM_130795.4) | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.2055C>G p.L685= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53705901; called by muse, mutect2, varscan2
- TPD52L1 | c.315C>T p.H105= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs141489966; called by muse, mutect2, varscan2
- TUBA4A | c.195A>T p.A65= | Silent (SNP) | VAF 57/226 reads (25%) | called by muse, mutect2, varscan2
- VPS4A | c.747G>C p.T249= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- AHR | c.*2959G>C | 3'UTR (SNP) | VAF 5/123 reads (4%) | called by muse, mutect2
- AL713998.1 | n.84T>A | RNA (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.384+8520G>A | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.*584A>G | 3'UTR (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.*19G>T | 3'UTR (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.1922-240C>T | Intron (SNP) | VAF 19/113 reads (17%) | catalogued as rs983459542; called by muse, mutect2, varscan2
- ATF4 | c.-494G>A | 5'UTR (SNP) | VAF 24/89 reads (27%) | catalogued as rs1364907772; called by muse, mutect2, varscan2
- ATP9A | c.*669A>T | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- ATR | c.6898-16A>T | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- BCL2 | c.*1435G>T | 3'UTR (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- BCLAF1 | c.*162G>A | 3'UTR (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- BRD1 | c.*299T>C | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- C2orf50 | c.*351C>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- CALN1 | c.*1143C>T | 3'UTR (SNP) | VAF 55/160 reads (34%) | catalogued as rs375270448; called by muse, mutect2, varscan2
- CCDC50 | c.*3562A>G | 3'UTR (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- CDC42BPA | c.-123A>T | 5'UTR (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- CDH11 | c.*3198A>C | 3'UTR (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- COL19A1 | c.*1030G>A | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-230382T>G | Intron (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- CTSC | c.318+10807T>G | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as rs1007407988; called by muse, mutect2, varscan2
- CYP19A1 | c.628+286C>T | Intron (SNP) | VAF 25/62 reads (40%) | catalogued as rs564101220; called by muse, mutect2, varscan2
- DHFR | c.*2206del | 3'UTR (DEL) | VAF 17/145 reads (12%) | called by mutect2, pindel, varscan2
- DIS3 | c.*2959T>C | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- DOCK4 | c.5014-601T>C | Intron (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- EPO | c.*512T>C | 3'UTR (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- EYS | c.1766+3418C>G | Intron (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- FGG | c.533-84C>A | Intron (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- FZD10 | c.-306C>G | 5'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- GABRB2 | c.*4173del | 3'UTR (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- GABRB3 | c.*70T>G | 3'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- GABRG1 | c.*542T>A | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- GALNT17 | c.-232G>T | 5'UTR (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- HABP2 | c.*919T>C | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- HEYL | c.*214C>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- HHLA1 | c.1469+1053G>C | Intron (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- HMCN1 | c.-5del | 5'UTR (DEL) | VAF 18/82 reads (22%) | catalogued as rs755887128; called by mutect2, varscan2
- HOXB3 | chr17:48545537 C>T | 3'Flank (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- IFI44 | c.*165A>C | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.-43A>G | 5'UTR (SNP) | VAF 7/11 reads (64%) | called by mutect2, varscan2
- IGLV3-1 | c.-48A>T | 5'UTR (SNP) | VAF 25/116 reads (22%) | called by muse, varscan2
- IKZF2 | c.406+105A>C | Intron (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- IL17RA | c.*5858A>C | 3'UTR (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- INSYN2A | c.*1397A>G | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- IPO4 | c.279-117A>G | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2
- IRX6 | c.-455C>T | 5'UTR (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- ISLR2 | c.*973C>T | 3'UTR (SNP) | VAF 27/116 reads (23%) | called by muse, mutect2, varscan2
- ITGA1 | c.*3401T>A | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- ITPRID1 | chr7:31653045 A>T | 3'Flank (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- KCNK2 | c.-49C>T | 5'UTR (SNP) | VAF 86/341 reads (25%) | catalogued as rs1308925350, COSV67218698; called by muse, mutect2, varscan2
- KLHL14 | chr18:32773684 T>C | 5'Flank (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- KRTAP22-1 | c.-32G>T | 5'UTR (SNP) | VAF 72/209 reads (34%) | called by muse, mutect2
- LAMB2 | c.1890+35C>A | Intron (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- LGALS9 | chr17:27630423 T>C | 5'Flank (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- MAP3K13 | c.*3752dup | 3'UTR (INS) | VAF 21/46 reads (46%) | catalogued as rs1486454976; called by mutect2, varscan2
- MIR5195 | chr14:106851126 T>G | 5'Flank (SNP) | VAF 63/215 reads (29%) | catalogued as rs569234583; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851252 T>G | 5'Flank (SNP) | VAF 54/178 reads (30%) | catalogued as rs555046741; called by muse, mutect2, varscan2
- MMP16 | c.*618A>T | 3'UTR (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- MTMR12 | c.*469G>A | 3'UTR (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- MYLK | c.5239-2334T>G | Intron (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- NACC2 | c.*3244G>C | 3'UTR (SNP) | VAF 71/144 reads (49%) | called by muse, mutect2, varscan2
- NANP | c.*1374C>T | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- NFATC2 | c.*1533G>C | 3'UTR (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- NHS | c.*1601T>G | 3'UTR (SNP) | VAF 51/74 reads (69%) | called by muse, mutect2, varscan2
- NPAS3 | c.385+154A>T | Intron (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- NTN4 | c.*193T>A | 3'UTR (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- OPRPN | c.*57C>A | 3'UTR (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- PAPPA | c.*1332T>C | 3'UTR (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- PDE3A | c.*3930_*3946del | 3'UTR (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel
- PLOD2 | c.*308T>G | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- PMPCA | c.*424G>A | 3'UTR (SNP) | VAF 28/93 reads (30%) | catalogued as rs555888715; called by muse, mutect2, varscan2
- PPP1R14C | c.*389A>C | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- PRDM16 | c.*1602T>C | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- PSG7 | c.1244-138T>G | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.*774T>G | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- RAB18 | c.*1964T>G | 3'UTR (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- RBFOX2 | c.*3276T>G | 3'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as rs1324700988; called by muse, mutect2, varscan2
- RIMBP2 | c.*751T>G | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- RNF144B | c.*3185G>C | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- RNF39 | c.*591T>C | 3'UTR (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- RSL24D1 | c.*1128A>G | 3'UTR (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- SART3 | c.*713G>A | 3'UTR (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- SCN11A | c.4327+304A>T | Intron (SNP) | VAF 49/98 reads (50%) | catalogued as COSV56573606; called by muse, mutect2, varscan2
- SEMA3A | c.*2900T>C | 3'UTR (SNP) | VAF 32/90 reads (36%) | catalogued as rs1036384401; called by muse, mutect2, varscan2
- SEMA3D | c.*153A>C | 3'UTR (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- SLC22A9 | c.-53C>A | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- SLC6A11 | c.623+1812T>C | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- SNPH | c.-47-294G>A | Intron (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- SPPL3 | c.*1111del | 3'UTR (DEL) | VAF 3/22 reads (14%) | called by mutect2*, pindel, varscan2*
- TECPR2 | c.*3186A>G | 3'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- TFAP2B | c.*167del | 3'UTR (DEL) | VAF 22/126 reads (17%) | catalogued as rs375026920; called by mutect2, varscan2
- TGFB3 | c.*242A>G | 3'UTR (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2, varscan2
- TIFAB | c.*4689G>A | 3'UTR (SNP) | VAF 79/206 reads (38%) | called by muse, mutect2, varscan2
- TLN1 | c.782+87C>G | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV59207348; called by muse, mutect2, varscan2
- TLN2 | c.-36-10059T>G | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- TMEM132B | c.*2130A>T | 3'UTR (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- TRIM29 | c.805-86C>T | Intron (SNP) | VAF 44/148 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10360+4501T>A | Intron (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- URGCP | c.202+501A>G | Intron (SNP) | VAF 48/365 reads (13%) | called by muse, mutect2, varscan2
- WDR59 | c.*70G>A | 3'UTR (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- WHAMMP2 | chr15:28764120 C>T | 3'Flank (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2, varscan2
- YPEL4 | c.*49C>A | 3'UTR (SNP) | VAF 22/83 reads (27%) | catalogued as rs765322413; called by muse, mutect2, varscan2
- ZC3H6 | c.*3531G>A | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.*583G>A | 3'UTR (SNP) | VAF 16/316 reads (5%) | catalogued as rs1188619970; called by muse, mutect2
- ZFPM2 | c.-166C>A | 5'UTR (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.*593C>T | 3'UTR (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- ZNF514 | c.*152T>A | 3'UTR (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- ZNF527 | c.*2094G>C | 3'UTR (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- ZNF716 | c.*745A>T | 3'UTR (SNP) | VAF 59/143 reads (41%) | called by muse, mutect2, varscan2
